Gene-level copy-number profile of tumor specimen C3N-04094-01 (profiled together with C3N-04094-02) from CPTAC case C3N-04094, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.7 years (14,514 days).
Specimen C3N-04094-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f80be767-a360-42dc-ba48-6f7bbef2cd05.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04094-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/c260c897-e043-49f0-b5c6-b596aa1e9afb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 9,766; copy number 2: 45,349; copy number 3: 2,389; copy number 4: 780; copy number 5: 63; copy number 6: 8; copy number 7: 2; copy number 8: 1; copy number 32: 2; copy number 34: 13; copy number 35: 7; copy number 40: 6; copy number 81: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes (within-gene range 0–2): AL449423.1, CDKN2B.
- chr11:134,563,396–134,986,799, 7 genes: AP004550.1, AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1.
- chr21:8,680,538–8,701,562, 2 genes: CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,185,071–56,687,366, 81 genes, copy number 5–81 (broad region; genes not listed).
- chr7:57,270,839–57,275,197, 1 gene, copy number 7: AC099654.3.
- chr7:57,770,619–62,275,678, 14 genes, copy number 5–35: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:66,070,904–66,420,543, 7 genes, copy number 34 (within-gene range 3–34): AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P.

Autosomal genes at a single copy (total copy number 1): 7,426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
